TCGA case TCGA-CG-4475 — Stomach Adenocarcinoma (TCGA-STAD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach; Tissue source site: Indivumed. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/cad2adc1-0f41-4651-9c80-ae9961e2dc8d

Demographics
Sex at birth: male; Country of residence at enrollment: Germany; Age at index: 76 years; Vital status: Alive.

Diagnoses (4)
1. Adenocarcinoma with mixed subtypes (the primary disease): ICD-O-3 morphology code: 8255/3; ICD-10 code: C16.9; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Stomach, NOS; Classification of tumor: primary; Age at diagnosis: 76.8 years (28,065 days); Year of diagnosis: 2010; AJCC staging edition: 7th; AJCC pathologic T: T3; AJCC pathologic N: N1; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Prior malignancy: yes; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Days to last follow up: 699 days (1.9 years).
   Pathology details: Lymph nodes positive: 2; Lymph nodes tested: 20.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS; adjuvant Radiation Therapy, NOS.
2. Prior malignancy of the prostate gland (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
3. Prior malignancy of the testis (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.
4. Prior malignancy of the bladder (histology not recorded by GDC).
   Recorded as not given: Pharmaceutical Therapy, NOS; Radiation Therapy, NOS.

Follow-up (2 entries)
- Days to follow up: 0 days; Disease response: Tumor Free.
- Days to follow up: 699 days (1.9 years); Disease response: Tumor Free.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-CG-4475-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.8; Intermediate dimension: 0.6; Shortest dimension: 0.4.
  Slide TCGA-CG-4475-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20.
  Slide TCGA-CG-4475-01A-01-TS1: Section location: Top; Percent tumor cells: 55; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 40.
- Sample TCGA-CG-4475-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-CG-4475-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: History neoadjuvant treatment: No; Prospective collection: No; Retrospective collection: Yes; Tumor status: Tumor free; Anatomic organ subdivision: Stomach (NOS); Lymph nodes examined: Yes; Cancer procurement city: Hamburg.
- Follow-up form: Lost to follow-up: No; New tumor event diagnosis indicator: No; Tumor status: Tumor free; Treatment outcome first course: Partial Remission/Response; Treatment outcome at TCGA followup: Partial Remission/Response.
- Other malignancy form 1: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Prostate; Other malignancy histological type: malignant neoplasm of prostate.
- Other malignancy form 1, Surgery: Days from index date to other malignancy surgery: -7701.
- Other malignancy form 2: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Testicle; Other malignancy histological type: Malignant neoplasm testis.
- Other malignancy form 2, Surgery: Days from index date to other malignancy surgery: -7336.
- Other malignancy form 3: Malignancy type: Prior Malignancy; Other malignancy anatomic site: Bladder; Other malignancy histological type: Malignant neoplasm of bladder.
- Other malignancy form 3, Surgery: Days from index date to other malignancy surgery: -6971.

GDC annotations on this case (curator notes; quoted as recorded):
- Item may not meet study protocol: This case was accepted into TCGA but the pathology report is not consistent with study specific metrics. The BCR will ICD code per the pathology report, which may not match the clinical data.
- Prior malignancy: Prior malignancy of the prostate, bladder, and testicle. No systemic chemotherpay or radiation.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 699 days; disease-specific survival: no event (censored), 699 days; progression-free interval: no event (censored), 699 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-CG-4475-01A-01D-1155-01): tumor purity 0.43, ploidy 3.02, whole-genome doublings 1.
